Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017981-03A.2 (aliquot TARGET-15-SJMPAL017981-03A.2-01D) from TARGET case TARGET-15-SJMPAL017981, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (184 days).
Specimen TARGET-15-SJMPAL017981-03A.2: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5919931b-a818-4755-a6ef-68eacd0ee8d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017981-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017981-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fc8ba97-1098-42bf-9807-f83c990d59a0

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 68/223 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2
- GRM1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51171747, COSV51300307; called by muse, mutect2
- HECTD4 | c.8011G>T p.A2671S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1429439643; called by muse, mutect2
- PRR23A | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs1374688182; called by muse, mutect2
- SLCO3A1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV59231265; called by muse, mutect2, varscan2
- CLPB | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GPR33 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2
- HRG | c.378C>A p.C126* | Nonsense Mutation (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- SLC25A40 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2
- TAOK1 | c.2410C>A p.Q804K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.445); called by muse, mutect2
- TNRC18 | c.7747G>A p.G2583R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ATG4B | c.495G>A p.A165= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs772331716, COSV100728598; called by muse, mutect2
- MICAL3 | c.5979G>T p.L1993= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SLC49A4 | c.1305C>A p.L435= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
